Somatic mutation profile of tumor specimen TCGA-EM-A2P1-06A (aliquot TCGA-EM-A2P1-06A-11D-A202-08) from TCGA case TCGA-EM-A2P1, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 33.7 years (12,320 days).
Specimen TCGA-EM-A2P1-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d56dd749-824a-41e4-a573-0ee43f70294d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A2P1-10A (Blood Derived Normal), aliquot TCGA-EM-A2P1-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/277a5942-9e2e-4714-8e39-b76f82f6c5a8

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- FCGRT | c.118C>G p.P40A | Missense Mutation (SNP) | VAF 64/261 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV55529708; called by muse, mutect2, varscan2
- OTX1 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as rs761081890, COSV56994831; called by muse, mutect2, varscan2
- GRAMD4 | c.586C>T p.L196= | Silent (SNP) | VAF 27/131 reads (21%) | catalogued as rs145387351; called by muse, mutect2, varscan2
- XRN1 | c.4509A>G p.Q1503= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV53812200; called by muse, mutect2, varscan2
- TRIM14 | c.*131G>A | 3'UTR (SNP) | VAF 49/198 reads (25%) | catalogued as COSV99271544; called by muse, mutect2, varscan2
